Somatic mutation profile of tumor specimen TCGA-P5-A5ET-01A (aliquot TCGA-P5-A5ET-01A-11D-A27K-08) from TCGA case TCGA-P5-A5ET, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 27.5 years (10,027 days).
Specimen TCGA-P5-A5ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a416f50-2f0a-4fc7-b37b-247726b4eb1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5ET-10A (Blood Derived Normal), aliquot TCGA-P5-A5ET-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab09c125-e498-4d3e-9f3d-d96b217cd582

The open-access MAF lists 25 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, In Frame Del 6, Silent 3, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1011_1013del p.D338del | In Frame Del (DEL) | VAF 12/62 reads (19%) | hotspot (GDC flag); called by pindel, varscan2
- ABCB1 | c.2230_2232del p.D744del | In Frame Del (DEL) | VAF 7/79 reads (9%) | catalogued as rs756214997; called by pindel, varscan2
- AC004997.1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.2); catalogued as rs1470134696, COSV53164198; called by muse, mutect2, varscan2
- AMZ2 | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 19/190 reads (10%) | catalogued as COSV63082960; called by muse, mutect2
- ARHGEF12 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV63104593; called by muse, mutect2, varscan2
- DOT1L | c.3748G>A p.D1250N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs927525441, COSV67109698; called by muse, mutect2
- FAM214A | c.2062A>G p.T688A | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs777932751, COSV55924066; called by muse, mutect2, varscan2
- HBP1 | c.1360C>G p.Q454E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV56017659, COSV99753389; called by muse, mutect2, varscan2
- IL6ST | c.748A>C p.K250Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61141199; called by muse, mutect2, varscan2
- MAP3K4 | c.4082T>G p.I1361S | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62333454; called by muse, mutect2
- MAPK15 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62028322; called by muse, mutect2, varscan2
- MBD4 | c.1088_1090del p.E363del | In Frame Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs758453457; called by mutect2, pindel, varscan2
- MLLT6 | c.1228T>A p.S410T | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.057); catalogued as rs1163025536; called by muse, mutect2, varscan2
- PRKCQ | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs781395221, COSV54111077; called by muse, mutect2, varscan2
- PRR19 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1297535293, COSV100004015, COSV56624041, COSV56625287; called by muse, mutect2, varscan2
- SLC38A10 | c.2917C>T p.Q973* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV66101337; called by muse, mutect2, varscan2
- TANC2 | c.4858C>T p.P1620S | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67334294; called by muse, mutect2, varscan2
- TREX1 | c.212_213del p.V71Gfs*30 (on ENST00000625293 / NM_033629.6; = p.V61Gfs*30 on NM_007248.5) | Frame Shift Del (DEL) | VAF 56/208 reads (27%) | catalogued as rs74689946; called by pindel, varscan2
- DST | c.21159_21161del p.R7055del (on ENST00000361203 / NM_001374722.1; = p.R4752del on NM_015548.5) | In Frame Del (DEL) | VAF 38/132 reads (29%) | called by pindel, varscan2
- EFR3A | c.681_683del p.E228del | In Frame Del (DEL) | VAF 29/122 reads (24%) | called by pindel, varscan2
- ZBTB20 | c.1844_1846del p.F615del (on ENST00000474710 / NM_001164342.2; = p.F542del on NM_015642.6 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- ATG2A | c.4719G>A p.G1573= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs762975865, COSV65966791; called by muse, mutect2, varscan2
- DLL1 | c.1137T>G p.G379= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV64537503; called by muse, mutect2
- NEB | c.14604G>A p.K4868= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs771844407, COSV51386029; called by muse, mutect2, varscan2
